Somatic mutation profile of tumor specimen TCGA-05-4430-01A (aliquot TCGA-05-4430-01A-02D-1265-08) from TCGA case TCGA-05-4430, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 59.9 years (21,884 days).
Specimen TCGA-05-4430-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 704a5661-837d-4d33-9c3f-aab8c05b7967.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-05-4430-10A (Blood Derived Normal), aliquot TCGA-05-4430-10A-01D-1265-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/76dce8cc-38ff-4ddf-8272-0e405d82f63a

The open-access MAF lists 279 somatic variants for this specimen: 218 protein-altering or splice-affecting, 55 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 197, Silent 55, Nonsense Mutation 10, Frame Shift Del 4, Intron 4, Splice Site 3, Splice Region 2, 3'UTR 1, In Frame Del 1, Frame Shift Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.746G>T p.R249M | Missense Mutation (SNP) | VAF 19/81 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as rs587782329, COSV52666526, COSV52668050, COSV52697169, COSV52713804; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA5 | c.4916G>A p.R1639K | Missense Mutation (SNP) | VAF 9/103 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.754); catalogued as COSV52219347; called by muse, mutect2
- ABCA9 | c.3896G>T p.C1299F | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.067); catalogued as COSV60621809; called by muse, mutect2, varscan2
- ABCC8 | c.3734G>C p.R1245T | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as COSV56847367; called by muse, mutect2, varscan2
- ABCF2 | c.1057G>T p.A353S | Missense Mutation (SNP) | VAF 25/165 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.384); catalogued as COSV55181380; called by muse, mutect2, varscan2
- ADAMTS12 | c.961T>A p.F321I | Missense Mutation (SNP) | VAF 44/131 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61257612; called by muse, mutect2, varscan2
- ADSS1 | c.194G>T p.G65V | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58272487; called by muse, varscan2
- AFF4 | c.2008G>A p.E670K | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.131); catalogued as rs1337466139, COSV54792531; called by muse, mutect2, varscan2
- AFTPH | c.687G>T p.E229D | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV53216439; called by muse, mutect2, varscan2
- AIMP1 | c.391G>C p.G131R | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0.006); catalogued as COSV100786180; called by muse, mutect2
- ALX1 | c.863G>T p.G288V | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.925); catalogued as rs531910111, COSV57491534; called by muse, mutect2, varscan2
- ANK2 | c.9103A>G p.I3035V | Missense Mutation (SNP) | VAF 18/171 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.978); catalogued as COSV52150532; called by muse, mutect2, varscan2
- ANO2 | c.2326C>A p.L776I (on ENST00000356134 / NM_001278597.3; = p.L780I on NM_001278596.3) | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV59011289; called by muse, mutect2
- APOB | c.4534G>T p.G1512C | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.972); catalogued as COSV51927123; called by muse, mutect2, varscan2
- ARHGAP31 | c.2672A>T p.D891V | Missense Mutation (SNP) | VAF 27/147 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.192); catalogued as COSV51790050; called by muse, mutect2, varscan2
- ARL4D | c.286G>T p.G96C | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100186433, COSV60721946; called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.716C>T p.S239F | Missense Mutation (SNP) | VAF 21/204 reads (10%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV63437261; called by muse, mutect2, varscan2
- ASXL2 | c.2105G>A p.G702E | Missense Mutation (SNP) | VAF 17/201 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.36); catalogued as COSV55455069; called by muse, mutect2
- ATG4A | c.791C>A p.A264E | Missense Mutation (SNP) | VAF 45/354 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100619540; called by muse, mutect2, varscan2
- ATP2B2 | c.3157T>A p.W1053R (on ENST00000352432; = p.W1019R on NM_001683.5) | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59491478; called by muse, varscan2
- BTAF1 | c.2791C>G p.P931A | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.031); catalogued as COSV56430987; called by muse, mutect2
- CA10 | c.943G>T p.A315S | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0.169); catalogued as COSV53341397; called by muse, mutect2
- CADPS | c.2730C>A p.A910= | Splice Region (SNP) | VAF 24/506 reads (5%) | catalogued as COSV51870972; called by muse, mutect2
- CBLN1 | c.398T>G p.L133R | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.83); PolyPhen possibly damaging (0.493); catalogued as COSV54653497; called by muse, mutect2
- CCDC80 | c.915C>A p.S305R | Missense Mutation (SNP) | VAF 21/129 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs1173666475, COSV52815480; called by muse, mutect2, varscan2
- CCIN | c.706G>T p.A236S | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.122); catalogued as COSV58724212; called by muse, mutect2, varscan2
- CD1E | c.710C>A p.P237Q | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63770304; called by muse, mutect2, varscan2
- CDHR1 | c.2200C>A p.L734M | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.026); catalogued as COSV60560338; called by muse, mutect2, varscan2
- CEP192 | c.6272G>T p.G2091V | Missense Mutation (SNP) | VAF 83/294 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.073); catalogued as COSV58061089; called by muse, mutect2, varscan2
- CEP85 | c.11A>T p.Q4L | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.007); catalogued as COSV53327653; called by muse, mutect2, varscan2
- CHRNE | c.688G>T p.V230F | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV53416765, COSV53417092; called by muse, mutect2, varscan2
- CLCN1 | c.59C>A p.P20H | Missense Mutation (SNP) | VAF 22/220 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV58368176; called by muse, mutect2
- CMYA5 | c.1762G>T p.V588F | Missense Mutation (SNP) | VAF 62/412 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.595); catalogued as COSV71404475; called by muse, mutect2, varscan2
- CNGA2 | c.1078G>T p.G360C | Missense Mutation (SNP) | VAF 18/182 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61703620; called by muse, mutect2
- CNR2 | c.407G>A p.R136H | Missense Mutation (SNP) | VAF 25/149 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs199631465, COSV65692640; called by muse, mutect2, varscan2
- CNTN3 | c.2890C>A p.L964M | Missense Mutation (SNP) | VAF 21/196 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV55165321, COSV55165359; called by muse, mutect2
- CNTNAP4 | c.434G>T p.R145I | Missense Mutation (SNP) | VAF 28/161 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV56669122; called by muse, mutect2, varscan2
- COL4A5 | c.748C>A p.P250T | Missense Mutation (SNP) | VAF 11/134 reads (8%) | SIFT tolerated (0.54); PolyPhen benign (0.14); catalogued as COSV60357657; called by muse, mutect2
- CPN2 | c.728T>A p.L243Q | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60469745; called by muse, mutect2, varscan2
- CPXM1 | c.194G>T p.R65L | Missense Mutation (SNP) | VAF 68/230 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs758525497, COSV101013675, COSV66044804; called by muse, mutect2, varscan2
- CSMD1 | c.7235G>A p.R2412H (on ENST00000520002; = p.R2411H on NM_033225.6) | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.066); catalogued as rs201439492; called by muse, mutect2, varscan2
- CUBN | c.4666G>T p.D1556Y | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100912841; called by muse, mutect2
- CYP2C19 | c.235G>T p.G79* | Nonsense Mutation (SNP) | VAF 25/142 reads (18%) | catalogued as rs1410213756, COSV64906876, COSV64907112; called by muse, mutect2, varscan2
- DCAF12L2 | c.1132C>T p.R378C | Missense Mutation (SNP) | VAF 20/226 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63580691; called by muse, mutect2
- DCLK3 | c.377G>A p.G126E | Missense Mutation (SNP) | VAF 33/283 reads (12%) | SIFT tolerated (0.6); PolyPhen benign (0.033); catalogued as COSV69362606; called by muse, mutect2, varscan2
- DNAH9 | c.9889A>T p.T3297S | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as COSV52339259; called by muse, mutect2, varscan2
- DRD3 | c.225C>A p.D75E | Missense Mutation (SNP) | VAF 14/145 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55679171; called by muse, mutect2
- DSG3 | c.2298G>T p.M766I | Missense Mutation (SNP) | VAF 19/117 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.05); catalogued as COSV57124799; called by muse, mutect2, varscan2
- DSPP | c.1276C>A p.P426T | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.028); catalogued as COSV56808627; called by muse, mutect2, varscan2
- DYM | c.1396G>A p.A466T | Missense Mutation (SNP) | VAF 5/81 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.71); catalogued as COSV99493340; called by muse, mutect2
- ERC1 | c.2217C>A p.H739Q (on ENST00000360905 / NM_178040.4; = p.H711Q on NM_178039.4) | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV61692480; called by muse, mutect2, varscan2
- FAM135B | c.1160G>T p.S387I | Missense Mutation (SNP) | VAF 27/178 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as COSV52711457; called by muse, mutect2, varscan2
- FAM153A | c.29-1G>T p.X10_splice | Splice Site (SNP) | VAF 11/170 reads (6%) | catalogued as COSV100646958, COSV100647055; called by muse, mutect2
- FAM47A | c.1087_1088insT p.R363Lfs*33 | Frame Shift Ins (INS) | VAF 8/78 reads (10%) | catalogued as COSV100649937; called by mutect2, varscan2
- FAT3 | c.4640G>T p.R1547I | Missense Mutation (SNP) | VAF 9/151 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV53086326; called by muse, mutect2
- FLG2 | c.3529A>G p.T1177A | Missense Mutation (SNP) | VAF 20/183 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.013); catalogued as COSV66167210; called by muse, mutect2, varscan2
- FLT3 | c.2565G>T p.M855I | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54047193; called by muse, mutect2, varscan2
- FOCAD | c.3013A>T p.T1005S | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.095); catalogued as COSV58095126; called by muse, mutect2
- FOXI1 | c.491A>T p.K164M | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60388228; called by muse, mutect2, varscan2
- FRMPD3 | c.5036C>A p.A1679D | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99346462; called by muse, mutect2
- FUT11 | c.518G>A p.R173H | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs368590019; called by muse, mutect2, varscan2
- GALNT15 | c.1300del p.L434* | Frame Shift Del (DEL) | VAF 30/169 reads (18%) | catalogued as COSV60216600; called by mutect2, pindel, varscan2
- GATAD1 | c.381C>G p.I127M | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.809); catalogued as COSV55319283; called by muse, mutect2, varscan2
- GNG11 | c.203G>T p.G68V | Missense Mutation (SNP) | VAF 9/109 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV50350179, COSV99949334; called by muse, mutect2
- GPA33 | c.617C>A p.S206* | Nonsense Mutation (SNP) | VAF 29/137 reads (21%) | catalogued as COSV63300386, COSV63300512; called by muse, mutect2, varscan2
- GPI | c.357G>T p.M119I | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.094); catalogued as COSV62893493, COSV62894280; called by muse, mutect2, varscan2
- GRIN2A | c.4126C>A p.R1376S | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.028); catalogued as COSV58023359, COSV58024387; called by muse, mutect2, varscan2
- GUCY2F | c.889G>T p.V297F | Missense Mutation (SNP) | VAF 33/212 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.216); catalogued as COSV54299456; called by muse, mutect2
- HIRA | c.1588G>C p.A530P | Missense Mutation (SNP) | VAF 10/194 reads (5%) | SIFT tolerated (0.25); PolyPhen benign (0.123); catalogued as COSV54273109; called by muse, mutect2
- HSPA1L | c.1820C>T p.P607L | Missense Mutation (SNP) | VAF 6/143 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV65149955; called by muse, mutect2
- HTR5A | c.368T>C p.L123P | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs369204841; called by muse, mutect2, varscan2
- IFNA4 | c.307A>G p.S103G | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV101427067; called by muse, mutect2, varscan2
- IL13RA2 | c.188A>T p.K63M | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.701); catalogued as COSV54564316; called by muse, mutect2, varscan2
- INO80D | c.2302A>T p.T768S | Missense Mutation (SNP) | VAF 6/97 reads (6%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.013); catalogued as COSV68958323; called by muse, mutect2
- INTS6L | c.651T>A p.N217K | Missense Mutation (SNP) | VAF 30/222 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.275); catalogued as COSV66083853; called by muse, mutect2, varscan2
- ITGA4 | c.1283G>C p.S428T | Missense Mutation (SNP) | VAF 27/128 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.101); catalogued as COSV51998493; called by muse, mutect2, varscan2
- ITPKB | c.2029G>A p.A677T | Missense Mutation (SNP) | VAF 12/190 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.061); catalogued as rs1336927158, COSV55258343; called by muse, mutect2
- KAT6B | c.3350A>T p.Q1117L | Missense Mutation (SNP) | VAF 34/212 reads (16%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.885); catalogued as COSV54743621; called by muse, varscan2
- KCNH7 | c.649A>G p.K217E | Missense Mutation (SNP) | VAF 19/152 reads (13%) | SIFT tolerated (0.66); PolyPhen benign (0.065); catalogued as COSV59789519; called by muse, mutect2, varscan2
- KIF16B | c.2062C>A p.Q688K | Missense Mutation (SNP) | VAF 24/290 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.106); catalogued as COSV61702525; called by muse, mutect2
- KIF27 | c.2001T>G p.I667M | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.215); catalogued as COSV52825952; called by muse, mutect2
- LHX9 | c.987G>T p.Q329H | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.984); catalogued as COSV100435919; called by muse, mutect2, varscan2
- LILRB5 | c.376C>A p.L126I | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV60255511; called by muse, mutect2, varscan2
- LMCD1 | c.598G>A p.A200T | Missense Mutation (SNP) | VAF 22/145 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.942); catalogued as rs576471098, COSV50087543; called by muse, mutect2, varscan2
- LRP1B | c.13593C>A p.F4531L | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated, low confidence (0.41); PolyPhen possibly damaging (0.827); catalogued as COSV67196443; called by muse, mutect2, varscan2
- LRPPRC | c.592-1G>A p.X198_splice | Splice Site (SNP) | VAF 5/43 reads (12%) | catalogued as COSV53235185; called by muse, mutect2, varscan2
- LRRC59 | c.538A>G p.K180E | Missense Mutation (SNP) | VAF 30/239 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.14); catalogued as COSV56813930, COSV99869373; called by muse, mutect2, varscan2
- LRRTM1 | c.646C>A p.L216I | Missense Mutation (SNP) | VAF 28/180 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54439091; called by muse, mutect2, varscan2
- MAGEA12 | c.908C>A p.P303H | Missense Mutation (SNP) | VAF 20/284 reads (7%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.547); catalogued as COSV63294229, COSV63294317; called by muse, mutect2
- MAGEC1 | c.63T>A p.S21R | Missense Mutation (SNP) | VAF 17/157 reads (11%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.307); catalogued as COSV53569416; called by muse, mutect2, varscan2
- MAGEE1 | c.754C>A p.R252S | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0); catalogued as COSV63909207; called by muse, mutect2, varscan2
- MAGT1 | c.931G>T p.V311L (on ENST00000618282 / NM_001367916.1; = p.V343L on NM_032121.5) | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.075); catalogued as COSV63781056; called by muse, mutect2, varscan2
- MAMLD1 | c.339G>C p.L113F | Missense Mutation (SNP) | VAF 16/206 reads (8%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.813); catalogued as COSV53372776; called by muse, mutect2
- MAMLD1 | c.678G>C p.Q226H | Missense Mutation (SNP) | VAF 29/454 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as COSV53372805; called by muse, mutect2
- MAMLD1 | c.1381G>C p.E461Q | Missense Mutation (SNP) | VAF 20/258 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53372908; called by muse, mutect2
- MAPK7 | c.1766C>G p.P589R | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV55189658; called by muse, mutect2
- MED12 | c.1531G>T p.A511S | Missense Mutation (SNP) | VAF 37/243 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV61334455; called by mutect2, varscan2
- MOAP1 | c.946G>C p.D316H | Missense Mutation (SNP) | VAF 47/182 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.562); catalogued as COSV99365721; called by muse, mutect2, varscan2
- MOGS | c.2056G>A p.V686I | Missense Mutation (SNP) | VAF 20/158 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV51968519; called by muse, mutect2, varscan2
- MPP1 | c.1297T>A p.S433T | Missense Mutation (SNP) | VAF 20/150 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65729247; called by muse, mutect2, varscan2
- MUC16 | c.14044C>A p.Q4682K | Missense Mutation (SNP) | VAF 34/220 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.015); catalogued as rs750266237, COSV67452180; called by muse, mutect2, varscan2
- MYBPC2 | c.1916del p.P639Qfs*37 | Frame Shift Del (DEL) | VAF 9/64 reads (14%) | catalogued as COSV63095489; called by mutect2, pindel, varscan2
- MYH8 | c.4837G>C p.D1613H | Missense Mutation (SNP) | VAF 15/145 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as COSV67961281; called by muse, mutect2, varscan2
- MYH8 | c.4154G>T p.R1385L | Missense Mutation (SNP) | VAF 47/255 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV67961283; called by muse, mutect2, varscan2
- MYH9 | c.1660C>A p.P554T | Missense Mutation (SNP) | VAF 8/145 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.213); catalogued as COSV53383079, COSV53387833; called by muse, mutect2
- MYL10 | c.379G>T p.E127* | Nonsense Mutation (SNP) | VAF 12/67 reads (18%) | catalogued as COSV56207384; called by muse, mutect2, varscan2
- NEB | c.4354A>G p.I1452V | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.142); catalogued as rs751657802, COSV50845238; called by muse, mutect2, varscan2
- NEXMIF | c.493C>G p.L165V | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.073); catalogued as COSV50023458, COSV99279910; called by muse, mutect2
- NHS | c.2339T>C p.V780A | Missense Mutation (SNP) | VAF 28/272 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.121); catalogued as COSV66272451; called by muse, mutect2, varscan2
- NKAPL | c.165G>T p.W55C | Missense Mutation (SNP) | VAF 18/140 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as COSV100642529; called by muse, mutect2, varscan2
- NLRP2 | c.2627C>A p.A876D | Missense Mutation (SNP) | VAF 10/129 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV54753051; called by muse, mutect2
- NSD1 | c.6817T>G p.C2273G | Missense Mutation (SNP) | VAF 29/230 reads (13%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.541); catalogued as COSV61772184; called by muse, mutect2, varscan2
- NTRK2 | c.2347T>A p.Y783N (on ENST00000323115 / NM_001369534.1; = p.Y799N on NM_006180.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52857063; called by muse, mutect2, varscan2
- NXPH3 | c.596G>T p.C199F | Missense Mutation (SNP) | VAF 22/157 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100165537; called by muse, mutect2, varscan2
- OOEP | c.302G>T p.R101L | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.65); PolyPhen benign (0.271); catalogued as COSV100949896, COSV64859053; called by muse, mutect2, varscan2
- OR10R2 | c.754G>T p.E252* | Nonsense Mutation (SNP) | VAF 20/114 reads (18%) | catalogued as COSV63768571; called by muse, mutect2, varscan2
- OR2J3 | c.169C>A p.H57N | Missense Mutation (SNP) | VAF 50/340 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV101013625, COSV65848731; called by muse, mutect2, varscan2
- OR2T12 | c.239C>G p.A80G | Missense Mutation (SNP) | VAF 26/187 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as COSV100527807, COSV58776817; called by muse, mutect2
- OR2T2 | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.574); catalogued as COSV100737682; called by mutect2, varscan2
- OR4C15 | c.693G>C p.M231I (on ENST00000314644; = p.M177I on NM_001001920.2) | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.005); catalogued as rs1397255363, COSV100115551, COSV58951531; called by muse, mutect2, varscan2
- OR4D10 | c.767A>G p.Y256C | Missense Mutation (SNP) | VAF 26/232 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs374135249; called by muse, mutect2, varscan2
- OR51F2 | c.949A>T p.N317Y | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as COSV59064032; called by muse, mutect2
- OR52A5 | c.312G>T p.W104C | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); catalogued as COSV100263474, COSV56614769, COSV56617124; called by muse, mutect2, varscan2
- OR52K1 | c.263G>T p.W88L | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.424); catalogued as COSV56903418; called by muse, mutect2, varscan2
- OR8D1 | c.298C>A p.Q100K | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100766658; called by muse, mutect2
- OTOGL | c.6916A>G p.N2306D (on ENST00000547103; = p.N2297D on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54014537; called by muse, mutect2, varscan2
- P2RX7 | c.506C>G p.P169R | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55853831; called by muse, mutect2
- PALM2AKAP2 | c.73C>A p.H25N (on ENST00000259318 / NM_001136562.3; = p.H256N on NM_007203.5) | Missense Mutation (SNP) | VAF 38/212 reads (18%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV52174253; called by muse, mutect2, varscan2
- PAPPA2 | c.3195G>T p.L1065F | Missense Mutation (SNP) | VAF 69/298 reads (23%) | SIFT tolerated (0.7); PolyPhen benign (0.011); catalogued as COSV62792650; called by muse, mutect2, varscan2
- PCSK1 | c.382C>T p.Q128* | Nonsense Mutation (SNP) | VAF 6/45 reads (13%) | catalogued as COSV60734216; called by muse, mutect2, varscan2
- PDZD4 | c.1961G>T p.R654L | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.314); catalogued as COSV51245630, COSV51247928; called by muse, mutect2, varscan2
- PGK2 | c.154G>A p.D52N | Missense Mutation (SNP) | VAF 62/215 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.045); catalogued as COSV59163139; called by muse, mutect2, varscan2
- PHF6 | c.393C>A p.H131Q | Missense Mutation (SNP) | VAF 23/122 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59700291; called by muse, mutect2, varscan2
- PIEZO2 | c.7450C>A p.Q2484K | Missense Mutation (SNP) | VAF 6/95 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.524); catalogued as COSV53287241, COSV99555770; called by muse, mutect2
- PLCH1 | c.3065A>T p.N1022I (on ENST00000340059 / NM_001130960.2; = p.N1014I on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/114 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.1); catalogued as COSV58190209; called by muse, mutect2
- PPP1R1A | c.293G>T p.G98V | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV54490449, COSV54495587; called by muse, mutect2, varscan2
- PRDM10 | c.1287+1G>T p.X429_splice | Splice Site (SNP) | VAF 18/111 reads (16%) | catalogued as COSV58799834; called by muse, mutect2, varscan2
- PRKCG | c.933G>T p.L311F | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.108); catalogued as COSV54725017; called by muse, mutect2, varscan2
- PROS1 | c.1160C>T p.S387F | Missense Mutation (SNP) | VAF 30/160 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.876); catalogued as COSV67774605; called by muse, varscan2
- PTPRN2 | c.1168C>A p.Q390K | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV67027159; called by muse, mutect2, varscan2
- RAB33A | c.306G>T p.M102I | Missense Mutation (SNP) | VAF 22/139 reads (16%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.502); catalogued as COSV99924596; called by muse, mutect2, varscan2
- RASGRP3 | c.392G>A p.R131K | Missense Mutation (SNP) | VAF 12/125 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV67820881; called by muse, mutect2, varscan2
- RGS5 | c.131C>A p.P44Q | Missense Mutation (SNP) | VAF 28/193 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0.01); catalogued as COSV100009111; called by muse, mutect2, varscan2
- RGS5 | c.130C>A p.P44T | Missense Mutation (SNP) | VAF 30/191 reads (16%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as COSV100009116; called by muse, mutect2, varscan2
- RIMBP2 | c.2241C>A p.S747R | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55467193; called by muse, mutect2, varscan2
- RNF144B | c.79del p.L27Sfs*16 | Frame Shift Del (DEL) | VAF 16/102 reads (16%) | catalogued as rs1201245811; called by mutect2, pindel, varscan2
- RP1L1 | c.1195G>T p.G399W | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.932); catalogued as COSV66752859; called by muse, mutect2
- RPGR | c.2814C>A p.N938K (on ENST00000339363 / NM_001367249.1; = p.N733K on NM_000328.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as COSV58833108; called by muse, mutect2
- RSPO1 | c.11G>T p.G4V | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV62973745; called by muse, mutect2, varscan2
- RTL3 | c.326C>T p.P109L | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); catalogued as COSV58183466; called by muse, mutect2, varscan2
- RTL4 | c.356G>C p.S119T | Missense Mutation (SNP) | VAF 17/191 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.219); catalogued as COSV61205639; called by muse, mutect2
- RTP5 | c.741C>A p.F247L | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV58319288; called by muse, mutect2, varscan2
- RYR2 | c.13083G>T p.E4361D | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.376); catalogued as COSV63669844; called by muse, mutect2, varscan2
- SAMD9L | c.3221G>T p.G1074V | Missense Mutation (SNP) | VAF 21/149 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV59080194, COSV59082594; called by muse, mutect2, varscan2
- SGO1 | c.896A>G p.N299S | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.012); catalogued as COSV99768328; called by muse, mutect2
- SIRPA | c.416G>A p.G139D | Missense Mutation (SNP) | VAF 24/135 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61537158; called by muse, varscan2
- SKIDA1 | c.2576G>T p.G859V | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71610489; called by muse, mutect2, varscan2
- SLC25A26 | c.554G>A p.C185Y | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.666); catalogued as COSV60913724; called by muse, mutect2
- SLC35E4 | c.406G>C p.A136P | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100299236, COSV55899164; called by mutect2, varscan2
- SLC39A5 | c.931C>T p.R311* | Nonsense Mutation (SNP) | VAF 24/390 reads (6%) | catalogued as rs763604286, COSV57190915; called by muse, mutect2
- SLC44A5 | c.359A>T p.K120M | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV63759631; called by muse, mutect2, varscan2
- SLC6A2 | c.1012A>T p.N338Y | Missense Mutation (SNP) | VAF 30/182 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54914347; called by muse, mutect2, varscan2
- SLC7A13 | c.86C>A p.A29E | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV52533098; called by muse, mutect2
- SLIT3 | c.1766C>T p.T589I | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60596407; called by muse, mutect2, varscan2
- SLITRK2 | c.2374C>G p.R792G | Missense Mutation (SNP) | VAF 43/238 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.922); catalogued as COSV100158281, COSV59423685, COSV59428874; called by muse, mutect2, varscan2
- SPATA31D1 | c.926G>T p.C309F | Missense Mutation (SNP) | VAF 30/360 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.031); catalogued as COSV61193613; called by muse, mutect2
- SPATA31D1 | c.2737A>T p.R913W | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV61193629; called by muse, mutect2, varscan2
- SPATC1 | c.933T>A p.S311R | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.354); catalogued as COSV66298253; called by muse, mutect2
- STPG2 | c.860G>C p.G287A | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54789035; called by muse, mutect2, varscan2
- SYT16 | c.107C>A p.S36Y | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV70855420, COSV99067570; called by muse, mutect2, varscan2
- TANC2 | c.5116C>T p.R1706* | Nonsense Mutation (SNP) | VAF 19/288 reads (7%) | catalogued as COSV67331565; called by muse, mutect2
- TANGO6 | c.361C>T p.P121S | Missense Mutation (SNP) | VAF 42/307 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.03); catalogued as COSV55761913; called by muse, mutect2, varscan2
- TBR1 | c.886G>A p.G296R | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67417432; called by muse, mutect2, varscan2
- TCERG1 | c.715G>T p.A239S | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.93); PolyPhen benign (0.001); catalogued as COSV57034622; called by muse, mutect2
- TDGF1 | c.256G>T p.G86W | Missense Mutation (SNP) | VAF 23/217 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56125272; called by muse, mutect2, varscan2
- TDRD6 | c.2318C>T p.T773I | Missense Mutation (SNP) | VAF 62/114 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); catalogued as rs1018763679, COSV60174384; called by muse, mutect2, varscan2
- TENM1 | c.7453C>A p.Q2485K | Missense Mutation (SNP) | VAF 25/198 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.328); catalogued as COSV64427088; called by muse, mutect2, varscan2
- TET1 | c.2500T>G p.S834A | Missense Mutation (SNP) | VAF 21/303 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.444); catalogued as COSV65382832; called by muse, mutect2
- TGM6 | c.1915T>A p.C639S | Missense Mutation (SNP) | VAF 68/225 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.575); catalogued as COSV52478038; called by muse, mutect2, varscan2
- THOC2 | c.2396C>A p.S799* | Nonsense Mutation (SNP) | VAF 28/320 reads (9%) | catalogued as COSV55542077; called by muse, mutect2
- TIMM17B | c.80G>T p.G27V | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54429566; called by muse, mutect2
- TMEFF1 | c.556G>T p.V186F | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs770617613, COSV58491522; called by muse, varscan2
- TRBC2 | c.120C>G p.H40Q | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782027659; called by muse, mutect2, varscan2
- TRPA1 | c.2909A>T p.H970L | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.057); catalogued as COSV51557039; called by muse, mutect2, varscan2
- TRPC5 | c.1571A>T p.Y524F | Missense Mutation (SNP) | VAF 21/171 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); catalogued as rs3027722, COSV53286095; called by muse, mutect2, varscan2
- TRPM1 | c.340C>A p.P114T | Missense Mutation (SNP) | VAF 18/221 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.341); catalogued as COSV56631622; called by muse, mutect2
- TRRAP | c.609G>C p.E203D | Missense Mutation (SNP) | VAF 29/170 reads (17%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.899); catalogued as COSV62840818; called by muse, mutect2, varscan2
- TSHZ3 | c.2443C>A p.P815T | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.014); catalogued as COSV53666483; called by muse, mutect2, varscan2
- TSLP | c.87C>A p.Y29* | Nonsense Mutation (SNP) | VAF 21/173 reads (12%) | catalogued as COSV61291381, COSV61291548; called by muse, mutect2, varscan2
- TTBK1 | c.275G>T p.R92M | Missense Mutation (SNP) | VAF 13/217 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52489110; called by muse, mutect2
- TTLL1 | c.588C>A p.D196E | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV56738019; called by muse, mutect2
- TTN | c.98693C>A p.P32898H (on ENST00000591111; = p.P25474H on NM_003319.4) | Missense Mutation (SNP) | VAF 52/300 reads (17%) | PolyPhen probably damaging (0.999); catalogued as COSV59931392; called by muse, mutect2, varscan2
- TTN | c.88442T>A p.V29481D (on ENST00000591111; = p.V22057D on NM_003319.4) | Missense Mutation (SNP) | VAF 10/172 reads (6%) | PolyPhen possibly damaging (0.654); catalogued as COSV59931437; called by muse, mutect2
- TUB | c.882G>T p.K294N (on ENST00000299506 / NM_177972.3; = p.K349N on NM_003320.4) | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV55106971; called by muse, mutect2, varscan2
- UGT2B4 | c.108G>T p.W36C | Missense Mutation (SNP) | VAF 12/188 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59315714; called by muse, mutect2
- ULK3 | c.356A>T p.Q119L | Missense Mutation (SNP) | VAF 18/217 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.374); catalogued as COSV51510467; called by muse, mutect2
- UPF3B | c.691G>T p.E231* | Nonsense Mutation (SNP) | VAF 8/51 reads (16%) | catalogued as COSV52229489; called by muse, mutect2, varscan2
- USH2A | c.9054G>T p.G3018= | Splice Region (SNP) | VAF 7/54 reads (13%) | catalogued as COSV56338987; called by muse, mutect2, varscan2
- USP31 | c.2924G>A p.R975H | Missense Mutation (SNP) | VAF 17/168 reads (10%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs776961232, COSV54850208; called by muse, mutect2, varscan2
- USP46 | c.727A>T p.R243W | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV71512689; called by muse, mutect2, varscan2
- UTP15 | c.62A>T p.Q21L | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.15); catalogued as COSV57140612; called by muse, mutect2, varscan2
- WARS2 | c.581A>T p.Q194L | Missense Mutation (SNP) | VAF 15/128 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.102); catalogued as COSV52476526; called by muse, mutect2, varscan2
- WDR6 | c.2974C>T p.R992C | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs774514627, COSV58244197; called by muse, mutect2, varscan2
- WDTC1 | c.1252G>T p.A418S (on ENST00000319394 / NM_001276252.2; = p.A417S on NM_015023.5) | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV60087471; called by muse, mutect2, varscan2
- ZBTB21 | c.142T>G p.L48V | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60403454; called by muse, mutect2, varscan2
- ZFHX4 | c.5097G>T p.Q1699H | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV50592190; called by muse, mutect2
- ZGRF1 | c.1013T>A p.I338K | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV52199382; called by muse, mutect2
- ZNF492 | c.1328A>G p.H443R | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV71761737, COSV71761754; called by muse, mutect2, varscan2
- ZNF597 | c.61G>C p.V21L | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.713); catalogued as COSV57083816; called by muse, mutect2, varscan2
- ZNF674 | c.154G>T p.G52W | Missense Mutation (SNP) | VAF 15/122 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as COSV70378694; called by muse, mutect2, varscan2
- ZNF80 | c.470G>A p.G157E | Missense Mutation (SNP) | VAF 9/120 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV57360090; called by muse, mutect2
- ZNF81 | c.687G>C p.Q229H | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV58575234; called by muse, mutect2
- ZNF831 | c.546G>T p.K182N | Missense Mutation (SNP) | VAF 98/255 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64038225; called by muse, mutect2, varscan2
- ZSCAN31 | c.925G>T p.G309C | Missense Mutation (SNP) | VAF 39/250 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as COSV60180394; called by muse, mutect2, varscan2
- CYP1A1 | c.1347del p.F450Lfs*37 | Frame Shift Del (DEL) | VAF 18/212 reads (8%) | called by mutect2, pindel
- FAM209B | c.56_64del p.A19_F22delinsV | In Frame Del (DEL) | VAF 40/298 reads (13%) | called by mutect2, varscan2
- NEU4 | c.1189A>T p.S397C (on ENST00000391969 / NM_001167602.3; = p.S409C on NM_080741.4) | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- SPATA31A1 | c.1213C>A p.Q405K | Missense Mutation (SNP) | VAF 37/270 reads (14%) | SIFT tolerated (0.78); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ABCB8 | c.885G>C p.T295= (on ENST00000297504 / NM_001282291.2; = p.T278= on NM_007188.5) | Silent (SNP) | VAF 14/118 reads (12%) | catalogued as COSV52502853, COSV99874251; called by muse, mutect2, varscan2
- ANK2 | c.9570A>T p.V3190= | Silent (SNP) | VAF 9/65 reads (14%) | catalogued as COSV52150542; called by muse, mutect2, varscan2
- ATP1A3 | c.2055G>A p.L685= (on ENST00000545399 / NM_001256214.2; = p.L672= on NM_152296.5) | Silent (SNP) | VAF 16/90 reads (18%) | catalogued as COSV57485939; called by muse, mutect2, varscan2
- CD1C | c.294G>A p.E98= | Silent (SNP) | VAF 32/147 reads (22%) | catalogued as rs1245650033, COSV63805884; called by muse, mutect2, varscan2
- CDK5RAP1 | c.813G>T p.R271= | Silent (SNP) | VAF 18/130 reads (14%) | catalogued as COSV59426176; called by muse, mutect2, varscan2
- CECR2 | c.1797C>T p.P599= (on ENST00000342247 / NM_001290047.2; = p.P416= on NM_001290046.1) | Silent (SNP) | VAF 9/66 reads (14%) | catalogued as rs762003565, COSV52837647, COSV52847145; called by mutect2, varscan2
- CENPBD1 | c.63G>C p.A21= | Silent (SNP) | VAF 10/53 reads (19%) | catalogued as COSV99240546; called by muse, mutect2, varscan2
- CNTD1 | c.648C>T p.V216= | Silent (SNP) | VAF 15/172 reads (9%) | catalogued as COSV59311744; called by muse, mutect2
- COL3A1 | c.2601T>C p.G867= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as COSV58583820; called by muse, mutect2, varscan2
- CPD | c.1971C>T p.S657= | Silent (SNP) | VAF 20/189 reads (11%) | catalogued as COSV56711309; called by muse, mutect2, varscan2
- CPLX3 | c.147G>A p.K49= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as COSV100547731; called by muse, mutect2
- CSTF2 | c.936T>A p.P312= | Silent (SNP) | VAF 16/259 reads (6%) | catalogued as COSV65893574; called by muse, mutect2
- CYP27A1 | c.381G>T p.R127= | Silent (SNP) | VAF 12/114 reads (11%) | catalogued as COSV51467294; called by muse, mutect2, varscan2
- CYP3A5 | c.552T>C p.I184= | Silent (SNP) | VAF 23/143 reads (16%) | catalogued as COSV56118909; called by muse, mutect2, varscan2
- DGKK | c.3117T>C p.F1039= | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as COSV65706671; called by muse, mutect2, varscan2
- FAM13C | c.246C>G p.P82= | Silent (SNP) | VAF 11/90 reads (12%) | catalogued as COSV53244680; called by muse, mutect2, varscan2
- FASTKD3 | c.1275C>A p.A425= | Silent (SNP) | VAF 12/150 reads (8%) | catalogued as rs1169472415, COSV52942242; called by muse, mutect2
- FAT3 | c.8832C>A p.A2944= | Silent (SNP) | VAF 13/151 reads (9%) | catalogued as COSV53086350; called by muse, mutect2
- GALNTL6 | c.415C>T p.L139= | Silent (SNP) | VAF 22/123 reads (18%) | catalogued as COSV71826894; called by muse, mutect2, varscan2
- GFRAL | c.357A>C p.T119= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as COSV61229460; called by muse, mutect2, varscan2
- GPAT4 | c.1251G>A p.V417= | Silent (SNP) | VAF 11/72 reads (15%) | catalogued as COSV67840388; called by muse, mutect2, varscan2
- GRID1 | c.2442C>A p.T814= | Silent (SNP) | VAF 18/110 reads (16%) | catalogued as rs748739540, COSV60017974; called by muse, mutect2, varscan2
- HDGFL1 | c.168G>C p.L56= | Silent (SNP) | VAF 7/58 reads (12%) | catalogued as rs746548885, COSV57751394; called by muse, mutect2, varscan2
- HHIPL2 | c.753G>C p.L251= | Silent (SNP) | VAF 27/175 reads (15%) | catalogued as COSV58563674; called by muse, varscan2
- HNRNPR | c.732A>T p.A244= | Silent (SNP) | VAF 40/224 reads (18%) | catalogued as rs773968974, COSV56420301; called by muse, mutect2, varscan2
- IL25 | c.54A>T p.L18= | Silent (SNP) | VAF 32/124 reads (26%) | catalogued as COSV59305072; called by muse, mutect2, varscan2
- IL5RA | c.843T>C p.N281= | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as COSV56521830; called by muse, mutect2, varscan2
- MIER2 | c.765G>C p.G255= | Silent (SNP) | VAF 10/120 reads (8%) | catalogued as COSV53394511; called by muse, mutect2
- MOSPD2 | c.1275G>A p.Q425= | Silent (SNP) | VAF 38/229 reads (17%) | catalogued as COSV66859759; called by muse, mutect2, varscan2
- MROH1 | c.408G>T p.G136= | Silent (SNP) | VAF 4/54 reads (7%) | catalogued as COSV58188029; called by muse, mutect2
- NUTM1 | c.63C>T p.A21= | Silent (SNP) | VAF 10/110 reads (9%) | catalogued as COSV60995118; called by muse, mutect2
- OR1C1 | c.387C>T p.P129= | Silent (SNP) | VAF 11/66 reads (17%) | catalogued as COSV101376185, COSV68715511; called by muse, mutect2, varscan2
- OR51B2 | c.231T>A p.P77= | Silent (SNP) | VAF 22/80 reads (28%) | catalogued as COSV100173402; called by muse, mutect2, varscan2
- OR51L1 | c.258G>T p.V86= | Silent (SNP) | VAF 8/176 reads (5%) | catalogued as COSV58624157; called by muse, mutect2
- OR51V1 | c.405T>C p.Y135= | Silent (SNP) | VAF 9/78 reads (12%) | catalogued as COSV58314384; called by muse, mutect2, varscan2
- OR5AN1 | c.120G>T p.L40= | Silent (SNP) | VAF 18/288 reads (6%) | catalogued as COSV100004364; called by muse, mutect2
- OR8I2 | c.118T>C p.L40= | Silent (SNP) | VAF 27/208 reads (13%) | catalogued as rs1360830510, COSV56166937; called by muse, mutect2, varscan2
- OTOS | c.226C>T p.L76= | Silent (SNP) | VAF 22/103 reads (21%) | catalogued as COSV56227888; called by muse, mutect2, varscan2
- P4HB | c.606G>T p.G202= | Silent (SNP) | VAF 48/323 reads (15%) | catalogued as COSV58940329; called by muse, mutect2, varscan2
- PHOX2B | c.492G>T p.A164= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as COSV56930104, COSV99891323; called by mutect2, varscan2
- PRSS38 | c.738G>C p.G246= | Silent (SNP) | VAF 15/76 reads (20%) | catalogued as COSV64539836; called by muse, mutect2, varscan2
- SALL1 | c.2862C>T p.S954= | Silent (SNP) | VAF 10/73 reads (14%) | catalogued as rs775808496, COSV51754492; called by muse, mutect2, varscan2
- SLC17A1 | c.1380A>G p.K460= | Silent (SNP) | VAF 15/121 reads (12%) | catalogued as COSV55076907; called by muse, mutect2, varscan2
- SLC27A1 | c.918C>T p.I306= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as COSV53095877; called by muse, mutect2, varscan2
- SLITRK4 | c.960C>A p.A320= | Silent (SNP) | VAF 32/227 reads (14%) | catalogued as COSV62022546; called by muse, mutect2, varscan2
- SNTG1 | c.264C>G p.S88= | Silent (SNP) | VAF 4/41 reads (10%) | catalogued as COSV52430677, COSV52463000; called by muse, mutect2, varscan2
- SPATA31A3 | c.1821C>A p.I607= | Silent (SNP) | VAF 5/44 reads (11%) | called by mutect2, varscan2
- SRPK3 | c.645C>A p.P215= | Silent (SNP) | VAF 12/119 reads (10%) | catalogued as COSV54210109, COSV99473213; called by muse, mutect2, varscan2
- THBS2 | c.2484T>A p.G828= | Silent (SNP) | VAF 17/99 reads (17%) | catalogued as COSV64677478, COSV64682575; called by muse, mutect2, varscan2
- TSHZ1 | c.1203C>G p.G401= (on ENST00000580243 / NM_001308210.2; = p.G356= on NM_005786.6) | Silent (SNP) | VAF 6/62 reads (10%) | catalogued as COSV100433897, COSV59006702; called by mutect2, varscan2
- TSPAN15 | c.654C>A p.G218= | Silent (SNP) | VAF 8/141 reads (6%) | catalogued as COSV64782237; called by muse, mutect2
- USP9X | c.1887A>G p.L629= | Silent (SNP) | VAF 22/129 reads (17%) | catalogued as rs1277675996, COSV61066933; called by muse, mutect2, varscan2
- VWC2L | c.145C>A p.R49= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as COSV56966957, COSV56980994; called by muse, mutect2, varscan2
- XIRP2 | c.4317C>A p.S1439= (on ENST00000628543; = p.S1614= on NM_152381.6) | Silent (SNP) | VAF 7/54 reads (13%) | catalogued as COSV54687660; called by muse, mutect2, varscan2
- ZFP57 | c.1101G>A p.Q367= | Silent (SNP) | VAF 85/509 reads (17%) | catalogued as COSV65305793; called by muse, mutect2, varscan2
- DST | c.4297-1344A>G | Intron (SNP) | VAF 17/161 reads (11%) | catalogued as rs1481873946, COSV99757130; called by muse, mutect2, varscan2
- MACROD2 | c.1315+3318G>T | Intron (SNP) | VAF 15/47 reads (32%) | catalogued as COSV53956486; called by muse, mutect2, varscan2
- MRO | c.*2C>T | 3'UTR (SNP) | VAF 13/66 reads (20%) | catalogued as rs1267210039, COSV99839311; called by muse, mutect2, varscan2
- NTRK3 | c.1889+1782C>T | Intron (SNP) | VAF 3/25 reads (12%) | called by muse, mutect2
- PSG5 | c.431-2799C>A | Intron (SNP) | VAF 60/375 reads (16%) | catalogued as COSV100742576, COSV100742824; called by muse, mutect2, varscan2
- WASF4P | n.693G>A | RNA (SNP) | VAF 10/123 reads (8%) | called by muse, mutect2
